CCDI case PBCLZS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/536b638b-a8ea-40e7-99f5-3fd1d7824d07

Demographics
Sex at birth: female.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 0.9 years (331 days).

Biospecimens (2 samples)
- Sample 0DVBRA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DVBRJ: Tissue type: Tumor; Specimen type: Solid Tissue.
